TCGA case TCGA-3B-A9I1 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a4f68239-5b9f-40d7-9e52-b68efa170c1c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Dead; Days to death: 567 days (1.6 years).

Diagnoses (4)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 56.5 years (20,629 days); Year of diagnosis: 2012; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Sites of involvement: Lung, NOS / Uterus; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 9; Tumor length measurement: 18; Tumor width measurement: 9.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 10; Necrosis present: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 14; Tumor width measurement: 12.4.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 57.0 years (20,821 days); Days to diagnosis: 192 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.8; Tumor length measurement: 4.8; Tumor width measurement: 1.2.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 1.9; Tumor length measurement: 2; Tumor width measurement: 2.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 57.3 years (20,947 days); Days to diagnosis: 318 days; Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 3.7; Tumor width measurement: 4.6.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.7; Tumor width measurement: 0.9.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 57.3 years (20,947 days); Days to diagnosis: 318 days; Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.3; Tumor width measurement: 1.7.

Follow-up (5 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 2.
- Day 192 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 192 days; Discontiguous lesion count: 2.
- Day 318 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 318 days.
- Day 318 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 318 days.
- Days to follow up: 567 days (1.6 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-3B-A9I1-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9I1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9I1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: Yes; Discontinuous lesions count: 2; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 9; Lesion pathologic depth: 9.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 71; Days from index date to pharmaceutical treatment ended: 176; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 36; Days from index date to pharmaceutical treatment ended: 36; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 332; Days from index date to pharmaceutical treatment ended: 388; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 437; Days from index date to pharmaceutical treatment ended: 500; Pharmaceutical therapy drug name: Femara; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4, Therapy types: Pharmaceutical therapy type: Immunotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 567 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 567 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 192 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9I1-01A-11D-A38Y-01): tumor purity 0.96, ploidy 3.17, whole-genome doublings 1.
